Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEI-01A (Primary Tumor).

[page 1 of 2]
LINICAL DIAGNOSIS: R/O HCC

Specimen : r/o HCC

Gross Photo :

GROSS:

Specimen:

Liver: 8.0 x 6.5 x 3.0 cm, 73.0 gm (fresh)

Operation: Segmentectomy

Lesion: A well-defined mass

Size: 3.5 x 3.0 x 2.5 cm

Cut surface: Round to oval, pale tan, solid with granular appearance

Gross type

HCC: Nodular with perinodular extension

Resection margin:

Not involved grossly (safety margin: 1.2 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections are submitted.

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

JA 5/20/14

Gross photo: Present

Blocks

T1-4 and TB, solid mass and surrounding liver parenchyme x 5

A and NB, nontumorous liver parenchyme x 2

RM, resection margin of liver x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (20 %)

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

[page 2 of 2]
Intrahepatic metastasis: No
Multicentric occurrence: No

Non-tumor liver pathology

Dysplastic nodule: No
Ductal epithelial dysplasia: No
Other liver diseases: Cirrhosis, HCV associated

NOT reported. Gross:

NOT reported. Gross:

stomach,body,dissection,tubular adenoma,low grade,dysplasia

Large intestine, ascending colon, scopic, tubular adenoma, low grade, dysplasia
Large intestine, rectum, scopic, tubulovillous adenoma, high grade, dysplasia

Large intestine, rectum, scopic, erosion, chronic inflammation

Stomach, body, scopic, chronic gastritis
Stomach, antrum, scopic, chronic gastritis, dysplasia, low grade

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

DIAGNOSIS:

Liver, segment 8, segmentectomy: Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file 8583499d-8425-46da-b29e-83a81c08b5c3 (TCGA-DD-AAEI.405C1F31-C46C-4288-83BA-9BBFA4F7DF2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).